Somatic mutation profile of tumor specimen TCGA-91-A4BC-01A (aliquot TCGA-91-A4BC-01A-11D-A24D-08) from TCGA case TCGA-91-A4BC, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.0 years (21,565 days).
Specimen TCGA-91-A4BC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8e06bde-d36d-418c-bcee-6f03708def99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-91-A4BC-10A (Blood Derived Normal), aliquot TCGA-91-A4BC-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ea07ea8-c64e-4236-897b-13006bcda9f2

The open-access MAF lists 468 somatic variants for this specimen: 347 protein-altering or splice-affecting, 113 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 113, Nonsense Mutation 27, Splice Site 9, Frame Shift Del 9, Intron 2, RNA 2, 3'UTR 2, Frame Shift Ins 2, 3'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SELENBP1 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 22/250 reads (9%) | catalogued as rs1553204817, COSV100923616, COSV64373565; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADAT | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV100528633; called by muse, mutect2, varscan2
- AASDHPPT | c.878A>C p.D293A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV53788381, COSV99593295; called by muse, mutect2, varscan2
- ABHD16B | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs768118976, COSV99410673; called by muse, mutect2, varscan2
- ABI3BP | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99426653; called by muse, mutect2
- ACKR1 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.331); catalogued as COSV100929555; called by muse, mutect2, varscan2
- ACTBL2 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV101379327; called by muse, mutect2, varscan2
- ACTRT1 | c.597C>A p.S199R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100947537, COSV64420124; called by muse, mutect2, varscan2
- ADAM29 | c.2173C>A p.P725T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100822005; called by muse, mutect2, varscan2
- ADAMTS19 | c.1103A>T p.Q368L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV99177624; called by muse, mutect2, varscan2
- ADGRB3 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV101000613, COSV65419040; called by muse, mutect2
- ADGRL4 | c.1266A>C p.K422N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.131); catalogued as COSV66059621; called by muse, mutect2
- AK7 | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as COSV99967243; called by muse, mutect2, varscan2
- ALMS1 | c.6514C>T p.L2172F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1369555064, COSV100042356; called by muse, mutect2, varscan2
- AMOT | c.2115G>T p.Q705H (on ENST00000371959 / NM_001113490.1; = p.Q296H on NM_133265.3) | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100495004; called by muse, mutect2, varscan2
- ANKS1B | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs866244804, COSV100245739, COSV61365156; called by muse, mutect2, varscan2
- APBA1 | c.1300A>T p.R434* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99596021; called by muse, mutect2, varscan2
- APOB | c.8602G>C p.E2868Q | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99265507; called by muse, mutect2, varscan2
- APPL2 | c.963G>T p.L321F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV99314716; called by muse, mutect2, varscan2
- ARAP2 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100394605, COSV58287024; called by muse, mutect2, varscan2
- ARHGEF11 | c.4447G>A p.A1483T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1391722474, COSV59354095; called by muse, mutect2, varscan2
- ARHGEF11 | c.4025A>T p.Q1342L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV100168563; called by muse, mutect2, varscan2
- ARMC4 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99518562; called by muse, mutect2
- ASB2 | c.1624G>T p.A542S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.114); catalogued as COSV100279336; called by muse, mutect2, varscan2
- ASCC2 | c.1086-1G>T p.X362_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100316251; called by muse, mutect2, varscan2
- ASTN1 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100705161; called by muse, mutect2, varscan2
- ATP8A2 | c.3272C>G p.A1091G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV99681789; called by muse, mutect2, varscan2
- ATXN3L | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV101019382; called by muse, mutect2, varscan2
- AXIN2 | c.2243A>T p.K748I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100196451; called by muse, mutect2, varscan2
- B9D2 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99699137; called by muse, mutect2, varscan2
- BCL2 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100384309; called by muse, mutect2
- BLM | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100757207; called by muse, mutect2
- BMP5 | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100895957; called by muse, mutect2, varscan2
- BMPR1B | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV99215278; called by muse, mutect2
- BRINP2 | c.818T>C p.V273A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1312642703, COSV100838070; called by muse, mutect2, varscan2
- BRIP1 | c.1134G>C p.R378S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV99370057; called by muse, mutect2, varscan2
- CAMTA1 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100349164; called by muse, mutect2, varscan2
- CATSPER1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV100375907; called by muse, mutect2, varscan2
- CCDC151 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100710515; called by muse, mutect2
- CCDC66 | c.1674G>C p.K558N (on ENST00000394672 / NM_001353147.1; = p.K524N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413943, COSV100413952; called by muse, mutect2
- CCDC88C | c.2114A>G p.E705G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101105600; called by muse, mutect2, varscan2
- CD109 | c.2462C>A p.P821H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV99753521; called by muse, mutect2, varscan2
- CD44 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757127128, COSV99556569; called by mutect2, varscan2
- CDH11 | c.811A>T p.S271C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV51773833; called by muse, mutect2
- CDH3 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99868279; called by muse, mutect2
- CFAP47 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV52886475; called by muse, mutect2, varscan2
- CFAP91 | c.1589A>T p.H530L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99847095; called by muse, mutect2, varscan2
- CFHR5 | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV99888675; called by muse, mutect2, varscan2
- CHST12 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.623); catalogued as rs775707171, COSV51674095; called by muse, mutect2, varscan2
- CLUAP1 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); catalogued as COSV100489646; called by muse, mutect2
- CMKLR1 | c.491G>T p.W164L (on ENST00000312143 / NM_001142344.2; = p.W162L on NM_004072.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379370; called by muse, mutect2, varscan2
- CNTLN | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99263974; called by muse, mutect2
- COL15A1 | c.3802G>T p.A1268S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV100897640; called by muse, mutect2, varscan2
- COL17A1 | c.1624A>T p.S542C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as COSV100793161; called by muse, mutect2, varscan2
- COL19A1 | c.3421G>A p.G1141R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV100506219; called by muse, mutect2
- COLEC10 | c.221-2A>T p.X74_splice | Splice Site (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100250649; called by muse, mutect2
- CPEB4 | c.601A>G p.N201D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.118); catalogued as COSV99437072; called by muse, mutect2
- CSH2 | c.456G>T p.G152= | Splice Region (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100400209; called by muse, mutect2, varscan2
- CSMD1 | c.8668G>T p.E2890* (on ENST00000520002; = p.E2889* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV59300242, COSV99064756; called by muse, mutect2
- CSMD1 | c.3158C>G p.A1053G (on ENST00000520002; = p.A1052G on NM_033225.6) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.654); catalogued as COSV100147411, COSV59288574; called by muse, mutect2, varscan2
- CSMD3 | c.7654G>C p.D2552H (on ENST00000297405 / NM_001363185.1; = p.D2448H on NM_052900.3) | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99833438; called by muse, mutect2
- CSMD3 | c.3217G>A p.G1073R (on ENST00000297405 / NM_001363185.1; = p.G969R on NM_052900.3) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99833439; called by muse, mutect2
- CTCFL | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99712583; called by muse, mutect2
- CTNND2 | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 64/361 reads (18%) | catalogued as COSV100476170, COSV58876698; called by muse, varscan2
- CXXC5 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.681); catalogued as COSV100210708; called by muse, mutect2, varscan2
- CYP24A1 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398291; called by muse, mutect2, varscan2
- CYP4F3 | c.262T>A p.C88S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99658140; called by muse, mutect2, varscan2
- CYTL1 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.143); catalogued as COSV100312395, COSV57036586; called by muse, mutect2, varscan2
- DDX10 | c.2099G>T p.W700L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV100489465; called by muse, mutect2, varscan2
- DNAH9 | c.4914G>T p.K1638N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV52344789, COSV52344795, COSV52383239; called by muse, varscan2
- DSC3 | c.2066G>C p.G689A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100844594; called by muse, mutect2, varscan2
- DTX1 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99986342; called by muse, mutect2, varscan2
- DUSP3 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.102); catalogued as rs758918021, COSV99871466, COSV99871471; called by muse, mutect2, varscan2
- DYNC2H1 | c.519C>A p.S173R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV100518486; called by muse, varscan2
- DYNLRB2 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs775329487, COSV100009726; called by muse, mutect2, varscan2
- EBF3 | c.1240A>T p.S414C (on ENST00000355311 / NM_001375392.1; = p.S405C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as COSV100799184; called by muse, mutect2, varscan2
- EDARADD | c.519G>T p.Q173H (on ENST00000334232 / NM_145861.4; = p.Q163H on NM_080738.4) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100512730; called by muse, mutect2, varscan2
- EGFLAM | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.155); catalogued as COSV100471220, COSV59298402; called by muse, mutect2, varscan2
- EIF2D | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV99662759; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037094683, COSV100349103; called by muse, mutect2, varscan2
- EMID1 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV100468949; called by muse, mutect2, varscan2
- EPHA5 | c.3106C>A p.P1036T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV56631086, COSV99898621; called by muse, mutect2
- EPHA6 | c.2636G>T p.G879V (on ENST00000389672 / NM_001080448.3; = p.G271V on NM_173655.4) | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101062495; called by muse, mutect2
- EPHB1 | c.2346G>T p.L782F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67667693; called by mutect2, varscan2
- FAT3 | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV53129727, COSV99965741; called by muse, mutect2
- FAT4 | c.10456G>T p.D3486Y | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100628530, COSV58689671; called by muse, mutect2, varscan2
- FBN1 | c.4161C>G p.Y1387* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100354940, COSV57312193; called by muse, mutect2, varscan2
- FGD6 | c.3985G>A p.A1329T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100676557; called by muse, mutect2, varscan2
- FLG2 | c.1835G>T p.R612I | Missense Mutation (SNP) | VAF 31/497 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV101165838; called by muse, mutect2
- FLNC | c.4939G>A p.G1647S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs748563858, COSV100368059; called by muse, mutect2, varscan2
- FZD9 | c.1573G>T p.G525C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289743; called by muse, mutect2, varscan2
- GALC | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99729651; called by muse, mutect2, varscan2
- GALNT17 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100353853; called by muse, varscan2
- GEN1 | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.088); catalogued as COSV100437957; called by muse, mutect2, varscan2
- GIMAP8 | c.986T>A p.L329Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100217519; called by muse, mutect2, varscan2
- GLIS3 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100173919; called by muse, mutect2, varscan2
- GPR156 | c.1569G>T p.Q523H | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100251348; called by muse, mutect2, varscan2
- GPR89A | c.313+1G>T p.X105_splice | Splice Site (SNP) | VAF 36/221 reads (16%) | catalogued as COSV100572438; called by muse, mutect2, varscan2
- GRIA2 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV99644332; called by muse, mutect2, varscan2
- GRIK2 | c.2178G>C p.Q726H | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100025814; called by muse, mutect2
- GRIN2B | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101663024; called by muse, mutect2, varscan2
- GRIN3A | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | catalogued as COSV100701480, COSV62452322; called by muse, mutect2
- GRM7 | c.1894C>G p.L632V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63168789; called by muse, mutect2, varscan2
- GSDMA | c.329A>T p.N110I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); catalogued as COSV100053666; called by muse, mutect2, varscan2
- GUCY1A2 | c.1292A>T p.D431V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99974535, COSV99976871; called by muse, mutect2, varscan2
- GUCY2F | c.1642T>A p.F548I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99484937; called by muse, mutect2, varscan2
- HCN1 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs140758934, COSV57497778; called by muse, mutect2, varscan2
- HCN4 | c.2524C>A p.P842T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as COSV99983700; called by muse, mutect2, varscan2
- HDAC4 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100613361; called by muse, mutect2, varscan2
- HECA | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62769930; called by muse, mutect2
- HEPACAM2 | c.805G>T p.D269Y (on ENST00000394468 / NM_001039372.4; = p.D257Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100506541; called by muse, mutect2, varscan2
- HLA-DQA2 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100890712; called by muse, mutect2, varscan2
- HMX2 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.634); catalogued as COSV100378756; called by muse, mutect2, varscan2
- HNF4A | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100291356; called by muse, mutect2, varscan2
- HNF4A | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM082883, COSV100291357; called by muse, mutect2, varscan2
- IBTK | c.3145A>T p.T1049S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100090668; called by muse, mutect2, varscan2
- IFIT2 | c.199A>C p.N67H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV51080550; called by muse, mutect2, varscan2
- IGSF1 | c.3195del p.K1066Nfs*5 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as COSV100811722; called by mutect2, pindel, varscan2
- IGSF1 | c.3017G>T p.G1006V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as CX164156, COSV100812068, COSV63836412; called by muse, mutect2, varscan2
- IGSF1 | c.3016G>T p.G1006* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100812069; called by muse, mutect2, varscan2
- IL1R2 | c.258G>T p.M86I | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100207988, COSV60209310; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1702C>A p.H568N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100781238; called by muse, mutect2, varscan2
- IL22RA1 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV99582971; called by muse, mutect2
- INHBB | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.302); catalogued as COSV99735891; called by muse, mutect2, varscan2
- INSYN1 | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101138762; called by muse, mutect2, varscan2
- IRGC | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV99746283; called by muse, mutect2, varscan2
- ITGA4 | c.2610G>T p.M870I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101223319; called by muse, mutect2, varscan2
- ITGAX | c.2419G>T p.V807L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV99191679; called by muse, mutect2, varscan2
- ITIH5 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV99904585; called by muse, varscan2
- ITIH6 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.181); catalogued as COSV99513259; called by muse, mutect2
- JPH2 | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100881728; called by muse, mutect2, varscan2
- KATNAL1 | c.1239G>T p.E413D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV101016882; called by muse, mutect2, varscan2
- KCNH1 | c.193A>G p.S65G | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as COSV99659048; called by muse, mutect2, varscan2
- KCNK10 | c.1529A>G p.Q510R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as COSV100068267; called by muse, mutect2, varscan2
- KIAA1109 | c.6411G>T p.K2137N | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV99163014; called by muse, mutect2, varscan2
- KRTAP15-1 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.307); catalogued as rs1343605774, COSV100481624; called by muse, mutect2, varscan2
- KRTAP24-1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs1479063745, COSV100447413; called by muse, mutect2
- LAMB3 | c.500G>C p.S167T | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100620295; called by muse, mutect2
- LAMB4 | c.3289G>A p.G1097S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99223883; called by muse, mutect2, varscan2
- LCT | c.3919G>T p.G1307C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929409; called by muse, mutect2, varscan2
- LILRA1 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as rs893444156, COSV52182189, COSV99251894; called by muse, varscan2
- LRP1B | c.11946C>A p.N3982K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101256403; called by muse, mutect2, varscan2
- LRP6 | c.3509T>A p.I1170N | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99743215; called by muse, mutect2, varscan2
- LRRFIP1 | c.2322G>T p.L774F (on ENST00000392000 / NM_001137552.2; = p.L750F on NM_004735.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs1371173086, COSV99790735; called by muse, mutect2, varscan2
- LRRK1 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV99439697; called by muse, mutect2, varscan2
- MAGEB4 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974952, COSV66776611; called by muse, mutect2, varscan2
- MARCHF8 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100165757; called by muse, mutect2, varscan2
- MARF1 | c.1777A>C p.K593Q | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as COSV100705873; called by muse, mutect2
- MBTPS1 | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1335631844, COSV100597588; called by muse, mutect2, varscan2
- MBTPS1 | c.964-1G>T p.X322_splice | Splice Site (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100597590; called by muse, mutect2, varscan2
- MC5R | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 27/593 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100229027; called by muse, mutect2
- MC5R | c.967A>T p.R323* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV100229029; called by muse, mutect2
- MCM3AP | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52445622, COSV99386892; called by mutect2, varscan2
- MED4 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99319947, COSV99320113; called by muse, mutect2, varscan2
- MGAT1 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | PolyPhen probably damaging (0.944); catalogued as COSV100286647; called by muse, mutect2, varscan2
- MGAT1 | c.1212G>T p.M404I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | PolyPhen probably damaging (1); catalogued as COSV100286649; called by muse, mutect2, varscan2
- MLXIP | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100038736, COSV59838234; called by muse, mutect2, varscan2
- MMD2 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.471); catalogued as COSV101287002; called by muse, mutect2, varscan2
- MMP16 | c.1440G>T p.W480C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99688017; called by muse, mutect2
- MORC1 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV99226086; called by muse, mutect2
- MOS | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); catalogued as COSV100322825; called by muse, mutect2
- MOSPD2 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1050358567, COSV100996783, COSV66860169; called by muse, mutect2, varscan2
- MOV10L1 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99433701; called by muse, mutect2
- MROH2B | c.1103C>G p.T368R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV101270665; called by muse, mutect2
- MS4A14 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs770282821, COSV100280383; called by muse, mutect2, varscan2
- MTMR4 | c.3155T>A p.I1052N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV100051003; called by muse, mutect2, varscan2
- MXRA5 | c.5479G>A p.G1827R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99476824; called by muse, mutect2
- MYCBP2 | c.6397G>T p.A2133S (on ENST00000357337; = p.A2171S on NM_015057.5) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.935); catalogued as COSV100630280; called by muse, mutect2, varscan2
- MYH10 | c.5440G>A p.A1814T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1325448385, COSV99345125; called by muse, mutect2
- MYH13 | c.4125G>T p.W1375C | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99353853; called by muse, mutect2, varscan2
- MYH2 | c.986A>C p.Q329P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV99820062; called by muse, mutect2, varscan2
- MYH2 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs770317855, COSV99820063; called by muse, mutect2, varscan2
- MYH3 | c.3848C>A p.T1283N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV99878170; called by muse, mutect2, varscan2
- MYH4 | c.3866G>T p.G1289V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99701190; called by muse, mutect2, varscan2
- MYH8 | c.5504G>T p.R1835L | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV101238244, COSV67959512; called by muse, mutect2, varscan2
- MYL2 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as CM961006, COSV99960744; called by muse, mutect2, varscan2
- MYLK4 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99193753, COSV99193781; called by muse, mutect2, varscan2
- MYO7A | c.3050A>T p.Y1017F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV101289120; called by muse, mutect2, varscan2
- NCKAP5L | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100258747; called by muse, mutect2, varscan2
- NEB | c.3226G>T p.A1076S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1476900730, COSV99422064; called by muse, mutect2, varscan2
- NELL1 | c.1477T>C p.C493R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100121249; called by muse, mutect2, varscan2
- NPLOC4 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100480889; called by muse, mutect2
- NPTX2 | c.1165G>T p.V389F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV99674876; called by muse, mutect2, varscan2
- NR5A2 | c.1136A>G p.Q379R (on ENST00000367362 / NM_205860.3; = p.Q333R on NM_003822.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99371083; called by muse, mutect2, varscan2
- NRAP | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1304536527, COSV100748417; called by muse, mutect2
- NSD1 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100728997; called by muse, mutect2
- NUBP1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99296745; called by muse, mutect2, varscan2
- OGDHL | c.1477-1G>T p.X493_splice | Splice Site (SNP) | VAF 3/40 reads (8%) | catalogued as COSV65103156; called by muse, mutect2
- OLFML2A | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100053699; called by muse, mutect2
- OR14I1 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100700479; called by muse, varscan2
- OR1A1 | c.423T>A p.C141* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100410755, COSV58403473; called by muse, mutect2, varscan2
- OR1C1 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.309); catalogued as COSV101376219; called by muse, mutect2, varscan2
- OR1L1 | c.515G>C p.R172P (on ENST00000373686; = p.R122P on NM_001005236.3) | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100542135, COSV58937123; called by muse, mutect2, varscan2
- OR2AK2 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV100823617; called by muse, mutect2
- OR2T3 | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100613223; called by muse, mutect2, varscan2
- OR5W2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100747592; called by muse, mutect2, varscan2
- OR6N2 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100210134; called by muse, varscan2
- OR8G1 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100422402; called by muse, mutect2, varscan2
- PAK3 | c.1571C>A p.S524Y (on ENST00000262836 / NM_001324328.2; = p.S509Y on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53278648, COSV99457298; called by muse, mutect2, varscan2
- PAMR1 | c.1660C>T p.P554S (on ENST00000619888 / NM_001001991.3; = p.P571S on NM_015430.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99552559; called by muse, mutect2, varscan2
- PARD3B | c.1621-2A>T p.X541_splice | Splice Site (SNP) | VAF 9/63 reads (14%) | catalogued as COSV62530263; called by muse, mutect2, varscan2
- PCDH11Y | c.914C>A p.A305D (on ENST00000400457 / NM_032973.2; = p.A294D on NM_032971.3) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291388; called by muse, mutect2, varscan2
- PCDH19 | c.1253A>T p.Q418L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99719707; called by muse, mutect2, varscan2
- PCDHA11 | c.1609C>A p.R537S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV56479043, COSV56490464; called by muse, mutect2, varscan2
- PCDHAC1 | c.2866A>T p.S956C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99146921; called by muse, mutect2, varscan2
- PCDHB2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as rs1284086334, COSV99165101; called by muse, mutect2
- PCSK5 | c.2468A>T p.Y823F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as COSV100949979; called by muse, mutect2, varscan2
- PEAK1 | c.4174G>T p.G1392C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100432955; called by muse, mutect2, varscan2
- PEG3 | c.2246C>A p.A749E | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55633501, COSV99688824; called by muse, mutect2, varscan2
- PELP1 | c.3279G>T p.E1093D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV99342828; called by muse, mutect2, varscan2
- PGLYRP2 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99483985; called by muse, mutect2, varscan2
- PHF24 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV99646054; called by muse, mutect2, varscan2
- PIK3CG | c.403A>T p.I135F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100782852; called by muse, mutect2, varscan2
- PIR | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs953093600, COSV100990670; called by muse, mutect2, varscan2
- PLCB1 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV100570850, COSV100571797; called by muse, mutect2, varscan2
- PLCB4 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99595346; called by muse, mutect2, varscan2
- PLEKHG4B | c.2012G>T p.R671L (on ENST00000283426; = p.R1027L on NM_052909.5) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99360244; called by muse, mutect2
- POLG2 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV99857927; called by muse, mutect2, varscan2
- POTEE | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV100387843; called by muse, mutect2, varscan2
- PRDM10 | c.173A>T p.Y58F | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.733); catalogued as COSV100702023; called by muse, mutect2, varscan2
- PRDM9 | c.532A>T p.R178* | Nonsense Mutation (SNP) | VAF 28/147 reads (19%) | catalogued as COSV99690393; called by muse, mutect2, varscan2
- PRKG1 | c.1819A>T p.K607* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100907251; called by muse, mutect2, varscan2
- PRMT8 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54219973, COSV99713375; called by muse, mutect2, varscan2
- PSG3 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548960; called by muse, mutect2, varscan2
- PTK7 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100030134; called by muse, mutect2, varscan2
- PTPN2 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100518525, COSV58999606; called by muse, mutect2, varscan2
- PUM2 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100163611; called by muse, mutect2, varscan2
- PXDN | c.2152G>C p.A718P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1322508048, COSV53230847, COSV99413358; called by muse, mutect2
- R3HCC1L | c.1730G>T p.W577L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107070; called by muse, mutect2, varscan2
- RAB3IL1 | c.1078T>A p.F360I | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100076591; called by muse, mutect2, varscan2
- RAG2 | c.1457G>T p.R486I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV100271275; called by muse, mutect2, varscan2
- RB1CC1 | c.2281G>T p.V761L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as COSV99212234; called by muse, mutect2
- RBPMS2 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100264848; called by muse, mutect2, varscan2
- RC3H2 | c.1561G>T p.V521L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.042); catalogued as COSV100605573, COSV61800114, COSV61800280; called by muse, mutect2, varscan2
- RC3H2 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs925438604, COSV100106588; called by muse, mutect2, varscan2
- RDM1 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs148466061; called by muse, mutect2
- RGS9 | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99287447; called by muse, mutect2, varscan2
- RIMS2 | c.3896G>T p.S1299I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99169224; called by muse, mutect2, varscan2
- RNF11 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV99657940; called by muse, mutect2
- RNF112 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.257); catalogued as COSV101465410; called by muse, mutect2, varscan2
- RNF150 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV100153381; called by muse, mutect2, varscan2
- RNF220 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100698551; called by muse, mutect2, varscan2
- ROBO2 | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100166498; called by muse, mutect2, varscan2
- RP1 | c.1552G>T p.V518F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.31); catalogued as COSV99607366; called by muse, mutect2, varscan2
- RTL3 | c.1167C>A p.C389* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100329759; called by muse, mutect2, varscan2
- RYR2 | c.6329G>T p.G2110V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100769969; called by muse, mutect2, varscan2
- SAMD14 | c.718T>A p.W240R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99142946; called by muse, mutect2, varscan2
- SAMD9 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101180248; called by muse, mutect2, varscan2
- SASS6 | c.1614G>T p.Q538H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99790806; called by muse, mutect2, varscan2
- SCML2 | c.2009G>T p.S670I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99318936; called by muse, mutect2, varscan2
- SCN4B | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100228657; called by muse, mutect2, varscan2
- SCRN1 | c.75del p.N27Ifs*42 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV54128152; called by mutect2, pindel, varscan2
- SELP | c.1162C>G p.P388A | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.101); catalogued as COSV99739835; called by muse, mutect2
- SEMA4A | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780302871, COSV100740573, COSV61771841; called by muse, mutect2, varscan2
- SEMA5B | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99531691; called by muse, mutect2, varscan2
- SERPINA7 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100568312; called by muse, mutect2
- SETBP1 | c.4091C>T p.P1364L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99953165; called by muse, mutect2, varscan2
- SHC4 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100194534; called by muse, mutect2
- SHPK | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99843847; called by muse, mutect2
- SIPA1L2 | c.3049G>A p.V1017M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53391364; called by muse, mutect2, varscan2
- SLAMF7 | c.979A>T p.R327W | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100833275; called by muse, mutect2, varscan2
- SLC12A1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100372360; called by muse, mutect2, varscan2
- SLC35F3 | c.973G>T p.V325F (on ENST00000366617 / NM_001300845.1; = p.V394F on NM_173508.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.442); catalogued as rs377116741, COSV100784780; called by muse, mutect2, varscan2
- SLC6A6 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100692125; called by muse, mutect2, varscan2
- SLC9A9 | c.706T>G p.L236V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.875); catalogued as COSV100340640; called by muse, mutect2
- SLC9C2 | c.3268G>A p.A1090T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV100876740; called by muse, mutect2, varscan2
- SMARCC1 | c.2051A>T p.Q684L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV54379125, COSV99592762; called by muse, mutect2, varscan2
- SMTNL2 | c.548C>T p.P183L (on ENST00000389313 / NM_001114974.2; = p.P39L on NM_198501.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100130691; called by muse, mutect2, varscan2
- SNTG1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1335465159, COSV99387058; called by muse, mutect2
- SOX8 | c.1277C>A p.P426Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53508731, COSV99559220; called by muse, mutect2, varscan2
- SPAG11B | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as COSV99872981; called by muse, mutect2, varscan2
- SPATA31E1 | c.2869G>T p.G957W | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as COSV100350374, COSV57790999; called by muse, mutect2, varscan2
- SPOCK1 | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as COSV99968909; called by muse, mutect2, varscan2
- SPTA1 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100934454, COSV100934868; called by muse, mutect2, varscan2
- SSMEM1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52832942, COSV99927706; called by muse, mutect2, varscan2
- STRBP | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV100724038; called by muse, mutect2, varscan2
- STYXL2 | c.3182A>T p.N1061I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99609163; called by muse, mutect2, varscan2
- TAAR6 | c.336T>A p.D112E | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV99256671; called by muse, mutect2, varscan2
- TACR3 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); catalogued as rs758147513, COSV100510408; called by muse, mutect2, varscan2
- TAF1L | c.2118T>A p.N706K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99644620; called by muse, mutect2
- TAS2R38 | c.265A>T p.N89Y | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV101516422; called by muse, mutect2, varscan2
- TBL1X | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99482524; called by muse, mutect2, varscan2
- TCFL5 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV99415831; called by muse, mutect2, varscan2
- TDRD6 | c.1509G>T p.W503C | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100287544, COSV100287739; called by muse, mutect2, varscan2
- TECRL | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV67087666; called by muse, mutect2
- TENM1 | c.5055G>T p.E1685D | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100949945; called by muse, mutect2, varscan2
- TEX47 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99787275; called by muse, mutect2
- TG | c.5893T>A p.Y1965N | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99600713; called by muse, mutect2
- TIMMDC1 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99956154; called by muse, mutect2, varscan2
- TLL1 | c.1480G>T p.V494L | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99287198; called by muse, mutect2, varscan2
- TMEM161B | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99680484; called by muse, mutect2, varscan2
- TMEM177 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772808639, COSV55609653; called by muse, mutect2, varscan2
- TMEM177 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99733609; called by muse, mutect2, varscan2
- TMEM200A | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.788); catalogued as rs201963998; called by muse, mutect2, varscan2
- TP53BP1 | c.4415G>T p.G1472V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV99780474; called by muse, mutect2, varscan2
- TRIM11 | c.1032G>T p.W344C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488360; called by muse, mutect2
- TRIM38 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.732); catalogued as COSV100837568; called by muse, mutect2, varscan2
- TRPC5 | c.400A>T p.T134S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99460747; called by muse, mutect2, varscan2
- TSPEAR | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100553341, COSV59977038; called by muse, mutect2, varscan2
- TTN | c.39879C>A p.N13293K (on ENST00000591111; = p.N5869K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | PolyPhen benign (0.08); catalogued as COSV100611464; called by muse, mutect2, varscan2
- TUSC3 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101141371, COSV65887294; called by muse, mutect2, varscan2
- UBE2W | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100708814; called by muse, mutect2, varscan2
- UCK2 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100902966, COSV100902967; called by muse, mutect2, varscan2
- UGT2B11 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV101485247; called by muse, mutect2, varscan2
- UHRF2 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99436572; called by muse, mutect2, varscan2
- USF3 | c.4000G>C p.D1334H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100325213; called by muse, mutect2, varscan2
- USH2A | c.3158-1G>T p.X1053_splice | Splice Site (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100234109; called by muse, mutect2, varscan2
- USP34 | c.6419C>A p.S2140* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV101276996; called by muse, mutect2
- VWC2 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100514210; called by muse, mutect2
- WASHC2A | c.3092G>T p.R1031L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555524419, COSV99254621; called by muse, mutect2
- WDFY2 | c.187G>C p.V63L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53292816, COSV99987068; called by muse, mutect2, varscan2
- WSCD2 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV99774553; called by muse, mutect2, varscan2
- XIRP1 | c.1890C>A p.F630L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100453605; called by muse, mutect2, varscan2
- XPR1 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100851462; called by muse, mutect2, varscan2
- XRRA1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100369803; called by muse, mutect2, varscan2
- ZBTB16 | c.1509C>G p.S503R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV100251141, COSV100251438; called by muse, mutect2, varscan2
- ZDHHC19 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579568; called by muse, mutect2, varscan2
- ZKSCAN3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99356902; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1191553309, COSV101031963; called by muse, mutect2, varscan2
- ZNF25 | c.779G>C p.C260S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100224608; called by muse, mutect2, varscan2
- ZNF285 | c.1182C>A p.H394Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100449983; called by muse, mutect2, varscan2
- ZNF623 | c.1058G>C p.G353A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101513551; called by muse, mutect2, varscan2
- ZNF630 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV99332382; called by muse, mutect2
- ZNF630 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 15/137 reads (11%) | catalogued as COSV99332383; called by muse, mutect2
- ZNF681 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101267461; called by muse, mutect2
- CATSPERB | c.713-13_719del p.X238_splice | Splice Site (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- CREBBP | c.5026dup p.W1676Lfs*59 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel
- DDX3X | c.1742del p.G581Vfs*87 (on ENST00000399959; = p.G582Vfs*87 on NM_001356.5) | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- DMP1 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EMP3 | c.407del p.G136Dfs*? | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- GPR179 | c.4130C>A p.T1377N (on ENST00000621958; = p.T1376N on NM_001004334.4) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.220G>T p.E74* (on ENST00000354667 / NM_031243.3; = p.E62* on NM_002137.4) | Nonsense Mutation (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- IGHV1OR15-9 | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL9R | c.199del p.H67Tfs*98 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- INCENP | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MUC16 | c.17034_17035dup p.S5679Kfs*6 | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | called by pindel, varscan2
- MYCBP2 | c.5908_5918del p.E1970Lfs*15 (on ENST00000357337; = p.E2008Lfs*15 on NM_015057.5) | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, pindel
- NLGN1 | c.602del p.G201Afs*3 | Frame Shift Del (DEL) | VAF 10/109 reads (9%) | called by mutect2, pindel
- PCDHGA6 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); called by muse, mutect2
- POTEM | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PRAMEF4 | c.502T>A p.C168S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PRDM8 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- SCN3A | c.647_648del p.R216Nfs*33 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- SPATA31A3 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- THSD7B | c.3646_3647del p.C1216Qfs*2 (on ENST00000272643; = p.C1214Qfs*2 on NM_001316349.2) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by pindel, varscan2
- UTRN | c.1313A>T p.E438V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCD2 | c.663G>T p.V221= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100429412; called by muse, mutect2, varscan2
- ADCY2 | c.333G>A p.L111= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV100602787, COSV57868884; called by muse, mutect2, varscan2
- ADD2 | c.1971G>A p.T657= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs540699345, COSV100035555; called by muse, mutect2, varscan2
- ADGRG6 | c.2031G>T p.R677= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99747035; called by mutect2, varscan2
- AHNAK2 | c.11181C>T p.P3727= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV100317415; called by muse, mutect2
- ALG13 | c.639C>T p.S213= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99322158; called by muse, mutect2, varscan2
- ANGPT1 | c.426C>A p.T142= | Silent (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- ANK1 | c.3270G>A p.L1090= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99225142; called by muse, mutect2, varscan2
- APOBEC2 | c.147C>A p.A49= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99775367; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1536C>T p.N512= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100771909; called by muse, varscan2
- ATP12A | c.558C>A p.V186= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV99517576; called by muse, mutect2, varscan2
- ATP6V1E1 | c.138G>C p.V46= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99494270; called by muse, mutect2, varscan2
- ATP6V1G3 | c.21G>T p.G7= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV99810847; called by muse, mutect2, varscan2
- BACH1 | c.2154T>C p.S718= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99728202; called by muse, mutect2
- BAX | c.327G>T p.R109= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99509078; called by muse, mutect2, varscan2
- BRINP3 | c.2118C>T p.I706= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs878858161, COSV100818725, COSV66532301; called by muse, mutect2, varscan2
- CAMKK2 | c.1284C>T p.D428= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as COSV100242926; called by muse, mutect2
- CASKIN1 | c.312G>T p.A104= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100624069, COSV58872431; called by mutect2, varscan2
- CASP2 | c.483G>T p.V161= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV100130989; called by muse, mutect2, varscan2
- CCDC88C | c.4230C>T p.A1410= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs774077958, COSV100484857; called by muse, mutect2, varscan2
- CFAP43 | c.639T>C p.V213= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99530721; called by muse, mutect2, varscan2
- CHODL | c.771T>A p.S257= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV53047379, COSV99517858; called by muse, mutect2, varscan2
- CLSTN2 | c.1795C>A p.R599= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV71720917; called by muse, mutect2, varscan2
- COL4A1 | c.867C>A p.P289= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs144143608, COSV101011134; called by muse, mutect2, varscan2
- CPNE3 | c.609C>T p.Y203= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs376893060; called by muse, mutect2, varscan2
- CUX2 | c.2370C>G p.A790= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99919574; called by muse, mutect2, varscan2
- DNAH7 | c.7818G>A p.Q2606= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs1348499536, COSV100415093; called by muse, mutect2, varscan2
- DNAH9 | c.4977A>G p.K1659= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs1300636000, COSV99305736; called by muse, varscan2
- DYNC2LI1 | c.912G>A p.T304= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs374668170; called by muse, mutect2
- EEF1E1 | c.282G>C p.L94= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV101121251; called by muse, mutect2, varscan2
- ENPEP | c.1914G>T p.S638= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV54457333, COSV99487561; called by muse, mutect2, varscan2
- EPPK1 | c.4227G>T p.R1409= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101599830; called by muse, mutect2
- ERCC6L2 | c.1680A>G p.S560= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99998580; called by muse, mutect2, varscan2
- ESPL1 | c.1968C>T p.A656= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99229275; called by muse, mutect2, varscan2
- EYS | c.1179T>A p.P393= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV60989662; called by muse, mutect2
- FAM47A | c.2322T>A p.R774= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100649874; called by muse, mutect2, varscan2
- FGFR1 | c.1077G>T p.L359= (on ENST00000447712 / NM_023110.3; = p.L357= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100248107; called by muse, mutect2, varscan2
- FOXN2 | c.282A>G p.P94= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100489188; called by muse, mutect2
- GAS6 | c.1584C>A p.P528= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100581491; called by muse, mutect2, varscan2
- GPR12 | c.501C>A p.T167= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101197972; called by muse, mutect2, varscan2
- GRIA4 | c.693T>C p.H231= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99231252; called by muse, mutect2, varscan2
- GRM1 | c.1611G>C p.R537= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV99266035; called by muse, mutect2
- HDAC4 | c.177G>T p.L59= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100613365; called by muse, mutect2, varscan2
- HORMAD1 | c.315A>T p.P105= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100464084; called by muse, mutect2, varscan2
- HTR3C | c.1227C>A p.T409= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100570613; called by muse, mutect2
- IGHV3-35 | c.138C>T p.F46= | Silent (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- IL23R | c.402C>G p.V134= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV100724726; called by muse, mutect2, varscan2
- IQCF2 | c.163C>A p.R55= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100291046; called by muse, mutect2, varscan2
- ITGA3 | c.2436G>T p.G812= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1358669168, COSV50306718, COSV50318561, COSV99143612; called by muse, mutect2, varscan2
- ITGAD | c.2562C>G p.G854= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV101210460; called by muse, mutect2, varscan2
- ITK | c.577C>A p.R193= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs765859749, COSV101439707, COSV70062317; called by muse, mutect2, varscan2
- JAKMIP2 | c.411C>A p.A137= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV99508238; called by muse, mutect2
- KCNJ9 | c.330C>T p.A110= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100927741; called by muse, mutect2, varscan2
- KIF21B | c.3969A>T p.T1323= (on ENST00000422435 / NM_001252100.2; = p.T1310= on NM_017596.4) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100144466; called by mutect2, varscan2
- KRT6B | c.504G>A p.K168= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV99360686; called by muse, mutect2, varscan2
- KRTAP3-3 | c.45T>G p.P15= | Silent (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- LAMB1 | c.2040G>C p.V680= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99740643; called by muse, mutect2, varscan2
- LMX1A | c.180G>T p.V60= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99672216; called by mutect2, varscan2
- LRP6 | c.4176T>C p.F1392= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs1377876993, COSV99743213; called by muse, mutect2, varscan2
- LVRN | c.291C>G p.R97= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100773356, COSV100773438; called by muse, mutect2, varscan2
- MANBA | c.2097G>T p.G699= (on ENST00000642252; = p.G653= on NM_005908.4) | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99898655; called by muse, mutect2, varscan2
- MARCHF4 | c.1098C>T p.G366= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs781678179, COSV99814323; called by muse, mutect2, varscan2
- MARK1 | c.732C>T p.G244= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs969507296, COSV65071587; called by muse, mutect2
- MEPCE | c.984G>A p.V328= | Silent (SNP) | VAF 47/161 reads (29%) | catalogued as rs779123125, COSV52769592; called by muse, mutect2, varscan2
- MLLT6 | c.1470T>G p.T490= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- MUC16 | c.17175C>A p.T5725= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV101199823, COSV67475984; called by muse, varscan2
- MYH8 | c.1593G>T p.L531= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV101238395; called by muse, mutect2
- NFRKB | c.726G>T p.T242= (on ENST00000446488 / NM_001143835.2; = p.T267= on NM_006165.3) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100451889; called by muse, mutect2, varscan2
- NODAL | c.567C>A p.A189= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99755454; called by muse, mutect2, varscan2
- OR11H1 | c.135G>T p.G45= | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as rs781121885, COSV99421777; called by muse, mutect2, varscan2
- OR1E2 | c.96G>A p.L32= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1424522984, COSV99943435; called by muse, mutect2
- OR5D13 | c.180C>A p.I60= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as COSV100686862, COSV62333807; called by muse, mutect2, varscan2
- PARP8 | c.228A>G p.L76= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1178541638, COSV99891337; called by muse, mutect2, varscan2
- PCDHGA5 | c.1968C>T p.A656= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as COSV99537631; called by muse, mutect2, varscan2
- PCSK7 | c.1068G>A p.E356= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs946545789, COSV100309353; called by muse, mutect2, varscan2
- PGC | c.333T>C p.S111= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100756975; called by muse, mutect2, varscan2
- PHF20L1 | c.282G>A p.L94= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55193992, COSV99621212; called by muse, varscan2
- PNLIP | c.654A>T p.V218= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- POTEE | c.30T>G p.A10= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100387842; called by mutect2, varscan2
- PRAMEF4 | c.501C>A p.T167= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- PROS1 | c.138T>A p.L46= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100820283; called by muse, mutect2, varscan2
- PRRG1 | c.21G>T p.T7= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV66157687; called by muse, mutect2, varscan2
- RCC2 | c.939C>T p.A313= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100965145; called by muse, mutect2, varscan2
- RRP1B | c.855C>T p.D285= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs149845147, COSV61478723; called by muse, mutect2, varscan2
- SARDH | c.393G>C p.R131= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100060737; called by muse, mutect2, varscan2
- SCN7A | c.4209C>A p.A1403= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV101313207; called by muse, mutect2, varscan2
- SETD7 | c.1065G>A p.V355= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs560193779, COSV99918482; called by muse, mutect2, varscan2
- SH2D3C | c.600C>A p.L200= (on ENST00000314830 / NM_170600.3; = p.L43= on NM_005489.4) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100136881; called by muse, mutect2, varscan2
- SH3RF1 | c.1782A>T p.A594= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV99499002; called by muse, mutect2, varscan2
- SHANK1 | c.6255C>T p.P2085= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1171482245, COSV99521121; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC22A8 | c.1455G>T p.G485= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV60325068, COSV60326450; called by muse, mutect2, varscan2
- SLC24A1 | c.51A>T p.T17= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV99978242; called by muse, mutect2, varscan2
- SLC41A1 | c.786C>T p.G262= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs762387263, COSV100900383; called by muse, mutect2, varscan2
- SLC6A19 | c.621C>A p.V207= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV100443436; called by muse, mutect2, varscan2
- SSTR1 | c.1086C>A p.A362= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV57457748; called by muse, mutect2, varscan2
- SYNM | c.2349G>A p.L783= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100152725; called by muse, mutect2
- TAF6L | c.1074C>T p.V358= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV53667279; called by muse, mutect2, varscan2
- THSD7A | c.1377C>A p.I459= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101448692; called by muse, mutect2, varscan2
- THSD7B | c.309C>A p.L103= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99747950, COSV99750059; called by muse, mutect2, varscan2
- TIE1 | c.1887C>A p.G629= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100992066, COSV65251138; called by muse, mutect2, varscan2
- TIMM23 | c.223C>T p.L75= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- TMTC1 | c.2574G>C p.L858= (on ENST00000539277 / NM_001193451.2; = p.L750= on NM_175861.3) | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV99759595; called by muse, mutect2, varscan2
- TNC | c.1350C>T p.V450= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs759590939, COSV60789219; called by muse, mutect2, varscan2
- TNN | c.3165C>A p.T1055= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99511906; called by muse, mutect2
- TRRAP | c.6153C>T p.S2051= (on ENST00000359863 / NM_001244580.1; = p.S2033= on NM_003496.3) | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs781783001, COSV100722448; called by muse, mutect2, varscan2
- TTC7A | c.342G>A p.R114= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99766378; called by muse, mutect2
- TTN | c.4407A>G p.L1469= (on ENST00000591111; = p.L1423= on NM_003319.4) | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100611469; called by muse, mutect2, varscan2
- UBAP2L | c.2277C>G p.G759= | Silent (SNP) | VAF 5/107 reads (5%) | catalogued as COSV99671212; called by muse, mutect2
- UNC5C | c.81C>A p.A27= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV101497889; called by mutect2, varscan2
- ZNF165 | c.15A>T p.P5= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV101055919; called by muse, mutect2, varscan2
- ZNF385D | c.303C>A p.G101= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99874600; called by muse, mutect2, varscan2
- ZNF804B | c.4035C>G p.S1345= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV100302006, COSV100303641; called by muse, mutect2, varscan2
- ZNRF4 | c.882C>T p.C294= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99706494; called by muse, mutect2, varscan2
- AL136982.4 | n.971G>T | RNA (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- CLU | c.-53G>C | 5'UTR (SNP) | VAF 12/88 reads (14%) | catalogued as rs756245993, COSV100324287; called by muse, mutect2, varscan2
- DYRK2 | c.*5_*9del | 3'UTR (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- GBA3 | c.59-8191C>A | Intron (SNP) | VAF 15/142 reads (11%) | catalogued as rs1163120892; called by muse, mutect2, varscan2
- HERC2P3 | n.760G>T | RNA (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- MTRNR2L6 | chr7:142671026 T>C | 3'Flank (SNP) | VAF 67/161 reads (42%) | catalogued as rs778068959; called by muse, mutect2, varscan2
- PLOD1 | c.741+130C>T | Intron (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- SERPINB3 | c.*2T>C | 3'UTR (SNP) | VAF 9/137 reads (7%) | catalogued as COSV99379852; called by muse, mutect2
